CCDI case PBCAUZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/e08bd921-d161-4ad0-a76d-30995cbb2e35

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 25.8 years (9,415 days).

Biospecimens (2 samples)
- Sample 0DMOXI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMOXN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
